Somatic mutation profile of tumor specimen TCGA-50-5942-01A (aliquot TCGA-50-5942-01A-21D-1753-08) from TCGA case TCGA-50-5942, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 67.8 years (24,781 days).
Specimen TCGA-50-5942-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56b2a13b-1539-4ef2-ae60-e5a29c673f9a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-50-5942-10A (Blood Derived Normal), aliquot TCGA-50-5942-10A-01D-1753-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3e44a213-5858-411a-80be-23104fb8066f

The open-access MAF lists 57 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 11, Nonsense Mutation 6, Splice Site 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- RARA | c.856T>A p.F286I | Missense Mutation (SNP) | VAF 10/62 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99564915; called by muse, mutect2, varscan2
- RARA | c.857T>C p.F286S | Missense Mutation (SNP) | VAF 10/60 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54194067, COSV54195350; called by muse, mutect2, varscan2
- ALG9 | c.1357C>T p.P453S (on ENST00000614444 / NM_001352418.1; = p.P460S on NM_024740.2) | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.226); catalogued as COSV67644516; called by muse, mutect2, varscan2
- ANKRD17 | c.403T>G p.F135V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV58221409; called by muse, mutect2, varscan2
- BCKDHB | c.1141A>C p.K381Q | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV100243517; called by muse, mutect2, varscan2
- CCNC | c.625C>T p.Q209* | Nonsense Mutation (SNP) | VAF 5/50 reads (10%) | catalogued as COSV58334265; called by muse, mutect2
- CCZ1B | c.1266-2A>T p.X422_splice | Splice Site (SNP) | VAF 7/55 reads (13%) | catalogued as COSV51869775; called by muse, mutect2, varscan2
- CDH10 | c.1395C>G p.N465K | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.405); catalogued as COSV52583931; called by muse, mutect2
- CGNL1 | c.3262T>C p.S1088P | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.938); catalogued as COSV55569517; called by muse, mutect2
- DHX37 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs749064803, COSV100438971, COSV58134988; called by muse, mutect2, varscan2
- ELOA2 | c.963C>A p.D321E | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.038); catalogued as COSV55299359, COSV55300910; called by muse, mutect2
- FYB2 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 11/134 reads (8%) | catalogued as COSV100599132, COSV58585849; called by muse, mutect2
- GLYCTK | c.1358G>T p.G453V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99980777; called by muse, mutect2
- GPRASP2 | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV59991567; called by muse, mutect2
- GRIA2 | c.1297C>A p.H433N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99644176; called by muse, mutect2
- HPCA | c.244T>A p.F82I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100992173; called by muse, mutect2, varscan2
- IGHV3-21 | c.257G>T p.R86L | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.404); catalogued as rs200625829; called by mutect2, varscan2
- KCNH1 | c.184C>A p.Q62K | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as COSV55085818; called by muse, mutect2, varscan2
- KCNJ3 | c.1058C>A p.T353N | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs1419201362, COSV54537501; called by muse, mutect2
- KCTD3 | c.1578G>T p.Q526H | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.213); catalogued as rs747807604, COSV52067495; called by muse, mutect2, varscan2
- KIZ | c.824A>C p.N275T | Missense Mutation (SNP) | VAF 9/133 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.107); catalogued as COSV55685661; called by muse, mutect2
- KRT16 | c.714G>C p.E238D | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56967889, COSV56968379; called by muse, mutect2, varscan2
- MAN2A2 | c.1551A>C p.L517F | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as COSV64638588; called by muse, mutect2, varscan2
- MINAR1 | c.1487G>A p.G496D | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.025); catalogued as COSV59583624; called by muse, mutect2, varscan2
- NIPBL | c.8269C>T p.R2757C | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV56953705; called by muse, mutect2
- NRXN3 | c.1137C>A p.D379E (on ENST00000335750 / NM_001330195.2; = p.D6E on NM_004796.6) | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.819); catalogued as COSV59759384; called by muse, mutect2, varscan2
- PDZD2 | c.7756G>A p.D2586N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV56860779; called by muse, mutect2, varscan2
- PPP1R21 | c.2203A>T p.K735* (on ENST00000294952 / NM_001135629.3; = p.K724* on NM_152994.5) | Nonsense Mutation (SNP) | VAF 21/224 reads (9%) | catalogued as COSV54285491; called by muse, mutect2, varscan2
- RAPGEF2 | c.2522A>G p.Q841R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1320237927, COSV52429110; called by muse, mutect2
- RSF1 | c.3826C>T p.R1276* | Nonsense Mutation (SNP) | VAF 6/98 reads (6%) | catalogued as COSV57840838; called by muse, mutect2
- SETD2 | c.4999C>T p.Q1667* | Nonsense Mutation (SNP) | VAF 19/296 reads (6%) | catalogued as COSV57437153; called by muse, mutect2
- SETD2 | c.4622A>G p.N1541S | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV57439960; called by muse, mutect2, varscan2
- SLC12A1 | c.1189G>C p.G397R | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100372611, COSV57710043; called by muse, mutect2, varscan2
- SLC9C1 | c.451C>A p.P151T | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59889056, COSV59891027; called by muse, mutect2, varscan2
- SMAP2 | c.1164G>T p.Q388H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV101019003; called by muse, mutect2
- TMTC1 | c.1066G>T p.A356S (on ENST00000539277 / NM_001193451.2; = p.A248S on NM_175861.3) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV55484036, COSV55488620; called by muse, mutect2, varscan2
- TRPM6 | c.5525A>C p.Y1842S | Missense Mutation (SNP) | VAF 5/141 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV62512994; called by muse, mutect2
- UBD | c.27+1G>T p.X9_splice | Splice Site (SNP) | VAF 12/156 reads (8%) | catalogued as COSV100589671; called by muse, mutect2
- XIRP2 | c.5387G>A p.R1796K (on ENST00000628543; = p.R1971K on NM_152381.6) | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs766437963, COSV54700591; called by muse, mutect2, varscan2
- ZNF655 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV53158950; called by muse, mutect2, varscan2
- ZNF711 | c.1633C>A p.Q545K | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.015); catalogued as COSV52153293; called by muse, mutect2, varscan2
- CBWD3 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 10/90 reads (11%) | called by mutect2, varscan2
- SETD2 | c.4267dup p.D1423Gfs*6 | Frame Shift Ins (INS) | VAF 7/67 reads (10%) | called by mutect2, pindel, varscan2
- TRBV4-2 | c.143A>G p.H48R | Missense Mutation (SNP) | VAF 38/311 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ACSBG2 | c.1482T>G p.S494= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV53125464, COSV99397273; called by muse, mutect2
- ADA | c.870C>T p.Y290= | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100596113; called by muse, mutect2
- LAMB4 | c.3519T>C p.L1173= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV52721362; called by muse, mutect2, varscan2
- MAGEC3 | c.1713G>A p.V571= | Silent (SNP) | VAF 10/134 reads (7%) | catalogued as COSV53581546, COSV68924053; called by muse, mutect2
- OR2W3 | c.765C>A p.I255= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs1417801257, COSV100831648, COSV64457122; called by muse, mutect2
- OR4C15 | c.618C>T p.L206= (on ENST00000314644; = p.L152= on NM_001001920.2) | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV58953303; called by muse, mutect2
- PIGO | c.2025G>T p.A675= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as rs368209276, COSV53053933; called by muse, mutect2, varscan2
- PRDM7 | c.690G>A p.V230= | Silent (SNP) | VAF 13/53 reads (25%) | catalogued as COSV100371147; called by muse, mutect2, varscan2
- SLC8A1 | c.2766G>T p.V922= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV60483360; called by muse, mutect2, varscan2
- SPX | c.48G>T p.L16= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as COSV57020980; called by muse, mutect2
- UNC13C | c.4857A>G p.Q1619= | Silent (SNP) | VAF 6/57 reads (11%) | catalogued as COSV52846086, COSV52882868; called by muse, mutect2, varscan2
- TIPIN | c.475+1841G>T | Intron (SNP) | VAF 3/25 reads (12%) | catalogued as COSV99972357; called by muse, mutect2
